Gene-level copy-number profile of tumor specimen TCGA-56-A4ZK-01A from TCGA case TCGA-56-A4ZK, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.8 years (28,039 days).
Specimen TCGA-56-A4ZK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.1ed508c7-de81-4bfe-aec2-d85a34e64daa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-A4ZK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/58e107de-3389-4cbe-bee2-2f8a5045af58

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 2: 14,972; copy number 3: 10,069; copy number 4: 27,819; copy number 5: 1,029; copy number 6: 2,090; copy number 7: 2,692; copy number 8: 246; copy number 9: 640; copy number 10: 143; copy number 12: 30; copy number 17: 33; copy number 49: 21; copy number 71: 16.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:36,490,078–36,920,765, 9 genes (within-gene range 0–2): H2ACP1, SERTM1, GAPDHP34, TCEAL4P1, ARL2BPP3, NDE1P2, RFXAP, SMAD9, SMAD9-IT1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 883 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:36,768,122–37,034,515, 3 genes, copy number 9: AC117945.2, AC117945.1, GRIK3.
- chr3:141,324,213–182,617,810, 616 genes, copy number 9–49 (within-gene range 7–49) (broad region; genes not listed).
- chr3:194,402,672–198,222,513, 143 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr13:112,313,467–113,974,076, 49 genes, copy number 17–71: LINC01043, LINC01044, SPACA7, TUBGCP3, AL139384.2, ATP11AUN, AL139384.1, ATP11A, ATP11A-AS1, AL356752.1, MCF2L, AL356740.1, MCF2L-AS1, AL356740.2, AL356740.3, F7, F10, F10-AS1, KARS1P2, AL137002.2, PROZ, AL137002.1, PCID2, CUL4A, MIR8075, LDHBP1, LAMP1, GRTP1, AL136221.1, GRTP1-AS1, ADPRHL1, DCUN1D2, DCUN1D2-AS, RNU1-16P, TMCO3, AL442125.2, AL442125.1, TFDP1, ATP4B, TMEM255B, GAS6-AS1, GAS6, GAS6-DT, BX072579.1, LINC00454, BX072579.2, LINC00452, LINC00565, C13orf46.
- chr15:34,489,002–39,180,499, 71 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr15:39,019,193–39,026,521, 1 gene, copy number 9: AC087878.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
